TCGA case TCGA-CQ-7065 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: University Health Network, Toronto. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20ece2ca-8601-4cca-aec5-0a5c0b92594d

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 40 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 40.2 years (14,676 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,628 days (4.5 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 39; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 248 days; Days to treatment end: 294 days; Treatment dose: 7,000 cGy; Course number: 1; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 249 days; Days to treatment end: 291 days; Number of cycles: 3; Treatment dose: 477 mg; Prescribed dose: 197; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 47 days; Treatment outcome: No Measurable Disease.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 40.8 years (14,906 days); Days to diagnosis: 230 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (4 entries)
- Day 230 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 230 days.
- Days to follow up: 1,007 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,335 days (3.7 years); Disease response: Tumor Free.
- Days to follow up: 1,628 days (4.5 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CQ-7065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-CQ-7065-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CQ-7065-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-CQ-7065-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CQ-7065-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 1; Alcohol history documented: No.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form 1: New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event site: Oral Cavity; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,628 days; disease-specific survival: no event (censored), 1,628 days; disease-free interval: event (new tumor event after initially disease-free), 230 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 230 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CQ-7065-01A-11D-2077-01): tumor purity 0.75, ploidy 1.97, whole-genome doublings 0.
